Surgical pathology report (de-identified scan), TCGA case TCGA-56-8083, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8083-01A (Primary Tumor).

[page 1 of 3]
Surgical Pathology Report

* Final Report *

Result type: Surgical Pathology Report
Result date:
Result status:
Result title:
Performed by:
Verified by:
Encounter info:

* Final Report *

Clinical History

Left lung upper lobe mass

Specimen

- #1 R4 lymph node
- #2 L4 lymph node
- #3 Station 7 lymph node
- #4 Left upper lobe of lung, bronchial margins
- #5 Station 5 lymph node

Gross Examination

#1 Mediastinal (R4) lymph node biopsy: Received in the fresh state are three pieces of soft, black, and tan tissue, averaging 0.3 x 0.2 cm in diameter. A touch imprint is prepared, and the tissue is submitted entirely for frozen section evaluation.

#2 Mediastinal (L4) lymph node biopsy: Received in the fresh state are three pieces of soft, black tissue, ranging in size from 0.4-0.6 cm. A touch imprint is prepared, and the tissue is submitted entirely for frozen section evaluation.

#3 Mediastinal (level 7) lymph node biopsy: Received in the fresh state are multiple pieces of soft, black tissue, ranging in size from 0.4-0.7 cm. Submitted entirely for frozen section evaluation.

#4 Left lung, upper lobe: Received in the fresh state is a lung lobe weighing 25 gm and roughly 16.5 x 10.5 x 4.5 cm. Along the medial aspect of the upper lobe is a well circumscribed, nonencapsulated, soft, white tumor - roughly 3.5 x 3.5 x 2.5 cm. The nodule is roughly 2.5 cm from the bronchial margin and 0.4 cm from the overlying pleural surface. The remaining tissue is soft and pink. At the request of [REDACTED], the bronchial margin is submitted for frozen section ("FSA"). Subsequently, the tumor is sampled for frozen section ("FSB"). With the patient's expressed written consent, additional tissue is donated to the [REDACTED] Tumor Bank and Human DNA Genome Project. Tissue is submitted in eight additional blocks for permanent section. Block summary: "FSA" bronchial margin; "FSB" tumor; "A" bronchial tissue immediately distal to bronchial margin section; "B" additional bronchial tissue, distal to "A"; "C"- "F" tumor; "G" nontumorous lung (superior segment); "H" nontumorous lung (inferior segment). [REDACTED]

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surgical Pathology Report

* Final Report *

#5 Labeled Station 5 lymph node, is a soft, pink tan irregular fragment of tissue measuring 0.7 x 0.7 x 0.2 cm. It is bisected and totally submitted in cassette #5.

Frozen Section Diagnosis

- #1 MEDIASTINAL LYMPH NODE (R4), BIOPSY (1 TP, 1 FS): NEGATIVE.
- #2 MEDIASTINAL LYMPH NODE (L4), BIOPSY (1 TP, 1 FS): NEGATIVE.
- #3 MEDIASTINAL LYMPH NODE (LEVEL 7), BIOPSY (1 TP, 1 FS): NEGATIVE.
- #4 LEFT LUNG, UPPER LOBE (2 FS): SQUAMOUS CARCINOMA. BRONCHIAL MARGIN FREE.

Microscopic Examination

#1-#5 Microscopic examination performed.

Comment

The carcinoma is grossly 2.5 cm from the bronchial resection margin. Block "4A" (bronchial tissue obtained immediately distal to the bronchial margin section) contains a detached fragment of tumor in the bronchial lumen. The surrounding bronchial wall is unremarkable. A subsequent distal section of the bronchus ("4B") does not contain tumor. It appears that the bronchial lumen tumor fragment present in "4A" represents an artifact of specimen handling. Portions of this case have been reviewed in consultation with one additional departmental pathologist.

Signature Line

Signed by:
ELECTRONIC SIGNATURE

Final Diagnosis

- #1 MEDIASTINAL LYMPH NODE (R4), EXCISIONAL BIOPSY: FRAGMENTS OF BENIGN LYMPH NODE.
- #2 MEDIASTINAL LYMPH NODE (L4), EXCISIONAL BIOPSY: FRAGMENTS OF BENIGN LYMPH NODE.
- #3 MEDIASTINAL LYMPH NODE (LEVEL 7), EXCISIONAL BIOPSY: FRAGMENTS OF BENIGN LYMPH NODE.
- #4 LEFT LUNG, UPPER LOBE; EXCISION: POORLY DIFFERENTIATED SQUAMOUS CARCINOMA.
TUMOR SIZE: 3.5 X 3.5 X 2.5 CM.
PROXIMAL BRONCHIAL RESECTION MARGIN STATUS: FREE (SEE COMMENT).
PLEURAL SURFACE STATUS: NEGATIVE FOR CARCINOMA.
DIRECT EXTENSION OF TUMOR: ABSENT.
LYMPHOVASCULAR SPACE INVASION: ABSENT.
PERIBRONCHIAL LYMPH NODES: TWO LYMPH NODES, NO TUMOR PRESENT.

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surgical Pathology Report

* Final Report *

#5 MEDIASTINAL LYMPH NODE (STATION 5), EXCISIONAL BIOPSY: FRAGMENTS OF BENIGN LYMPH NODE.

PATHOLOGIC STAGE (TNM CLASSIFICATION): pT2a pN0.

Ordering Provider

Ordering Physician:

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file 57279384-c0e3-41ee-9dcb-353ec8b1fcc1 (TCGA-56-8083.9EC3009B-F666-48BC-ACD6-AC15FF81EB44.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).